MMRF case MMRF_2449 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2310d7bc-0e5a-4dc5-bf55-71d2336b843a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.2 years (20,529 days); ISS stage: III; Days to last known disease status: 751 days (2.1 years); Days to last follow up: 751 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 114 days; Days to treatment end: 114 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 116 days; Days to treatment end: 116 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 215 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 763 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 0.978 g/L; Immunoglobulin M 0.481 g/L; Beta 2 Microglobulin 7.5 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 10 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 399 µmol/L; Blood Urea Nitrogen 23.9 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 13.1 mmol/L.
- Day 72 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 4.25 g/L; Immunoglobulin A 0.839 g/L; Immunoglobulin M 0.305 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 9.57 mmol/L.
- Day 187 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 3.67 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.89 mmol/L.
- Day 277: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 3.56 g/L; Immunoglobulin A 0.372 g/L; Immunoglobulin M 0.244 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 6.11 mmol/L.
- Day 352: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 7.62 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 6.05 mmol/L.
- Day 459: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 543: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 4.18 mmol/L.
- Day 634: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 4.9 mmol/L.
- Day 751: M Protein 0 g/dL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 150 µmol/L; Calcium 2.28 mmol/L; Total Protein 6.8 g/dL.

Other clinical attributes
- Day 1: Weight: 67 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2449_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2449_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
